FM case AD5017 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Nasopharynx.
https://portal.gdc.cancer.gov/cases/c2415d77-732b-43b7-9a70-53e2bc708686

Male, 55.0 years: Squamous cell carcinoma, NOS (ICD-O-3 8070/3) of the overlapping lesion of nasopharynx; metastasis biopsied or resected from the lymph node. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Metastatic.
